Somatic mutation profile of tumor specimen C3L-06418-01 (aliquot CPT0422180006) from CPTAC case C3L-06418, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.4 years (24,990 days).
Specimen C3L-06418-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51ed9c22-c04d-4a5c-b3d1-3b0a0df1ddfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06418-31 (Blood Derived Normal), aliquot CPT0422160005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4efa9488-06aa-45f4-a8f5-42724de031c3

The open-access MAF lists 246 somatic variants for this specimen: 173 protein-altering or splice-affecting, 63 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 63, Nonsense Mutation 11, Frame Shift Del 8, Intron 7, Splice Site 1, 5'UTR 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.2269del p.V757Ffs*8 | Frame Shift Del (DEL) | VAF 27/216 reads (13%) | catalogued as rs80357583, CD972054; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC12 | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs549298261; called by muse, mutect2, varscan2
- ALDH16A1 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466158028; called by muse, mutect2, varscan2
- AP3M2 | c.26A>G p.N9S | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs1174550462; called by muse, mutect2, varscan2
- ATP11C | c.3259C>G p.L1087V | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV59569386; called by muse, mutect2, varscan2
- C1orf158 | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99847336; called by muse, mutect2, varscan2
- CALCOCO2 | c.1002A>C p.E334D | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1264371074; called by muse, mutect2, varscan2
- CCNE2 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1314344111; called by muse, mutect2, varscan2
- CLVS1 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs1193369258; called by muse, mutect2, varscan2
- CNKSR2 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs777809329, COSV54266419; called by muse, mutect2, varscan2
- CRPPA | c.314T>C p.M105T | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as rs770027292; called by muse, mutect2, varscan2
- CTAGE9 | c.1379A>G p.K460R | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs1387527322; called by muse, mutect2, varscan2
- DDR2 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1374086542, COSV63370517; called by muse, mutect2, varscan2
- DSEL | c.2480T>C p.L827S | Missense Mutation (SNP) | VAF 77/393 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs1358783280; called by muse, mutect2, varscan2
- ELFN1 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 73/455 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs977157332; called by muse, mutect2, varscan2
- EMILIN2 | c.2103G>T p.M701I | Missense Mutation (SNP) | VAF 72/335 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1258173236; called by muse, mutect2, varscan2
- EVI5 | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV64825495; called by muse, mutect2, varscan2
- EXOC3L1 | c.2218C>G p.R740G | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as rs1021980811; called by muse, mutect2, varscan2
- FLT3 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568745490, COSV54056209; called by muse, mutect2, varscan2
- HEATR6 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 68/451 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV51748536; called by muse, mutect2, varscan2
- HERC2 | c.9736C>T p.R3246W | Missense Mutation (SNP) | VAF 92/480 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1202104456, COSV55319234; called by muse, mutect2, varscan2
- IGKV3D-20 | c.38T>A p.L13H | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs560053996; called by muse, mutect2, varscan2
- ITCH | c.1076C>G p.P359R (on ENST00000262650 / NM_001257137.3; = p.P318R on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs888291691; called by muse, mutect2, varscan2
- KATNAL1 | c.713G>T p.R238I | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66062602; called by muse, mutect2, varscan2
- KIFC3 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 88/360 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1346449990; called by muse, mutect2, varscan2
- MCM3AP | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs556096598; called by muse, mutect2, varscan2
- MED12L | c.346del p.W116Gfs*5 | Frame Shift Del (DEL) | VAF 67/247 reads (27%) | catalogued as COSV56371516; called by mutect2, pindel, varscan2
- MED30 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 59/199 reads (30%) | catalogued as rs747290267, COSV99815916; called by muse, mutect2, varscan2
- MIEF2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 100/429 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs766984197; called by muse, mutect2, varscan2
- MNDA | c.495C>G p.S165R | Missense Mutation (SNP) | VAF 80/413 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.505); catalogued as rs1156496876, COSV63740596, COSV63741868; called by muse, mutect2, varscan2
- MON2 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs144560708, COSV54815144; called by muse, mutect2, varscan2
- MROH5 | c.3236G>A p.G1079E | Missense Mutation (SNP) | VAF 51/410 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs771584634; called by muse, mutect2, varscan2
- MSH5 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 76/371 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs139002853; called by muse, mutect2, varscan2
- MYH3 | c.4681C>T p.R1561* | Nonsense Mutation (SNP) | VAF 51/209 reads (24%) | catalogued as rs777408896, COSV56867863; called by muse, mutect2, varscan2
- NF1 | c.4824T>G p.Y1608* (on ENST00000358273 / NM_001042492.3; = p.Y1587* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | catalogued as CM076342, CM143418; called by muse, mutect2, varscan2
- NLRP2 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 112/506 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as rs771265449; called by muse, varscan2
- OR2D3 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760819035; called by muse, mutect2, varscan2
- PAPPA2 | c.4766G>A p.S1589N | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.345); catalogued as rs189427122; called by muse, mutect2, varscan2
- PHF11 | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV62896116; called by muse, mutect2, varscan2
- PIK3CB | c.3142G>C p.A1048P | Missense Mutation (SNP) | VAF 56/378 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100006262; called by muse, mutect2, varscan2
- POU5F1B | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 93/912 reads (10%) | catalogued as COSV101196937; called by muse, mutect2, varscan2
- PPP1R13L | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 84/523 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs1467952410; called by muse, mutect2, varscan2
- PRRT4 | c.2042C>G p.A681G | Missense Mutation (SNP) | VAF 98/511 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.423); catalogued as COSV101435693; called by muse, mutect2, varscan2
- RADIL | c.127T>C p.F43L | Missense Mutation (SNP) | VAF 78/422 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs754804357; called by muse, mutect2, varscan2
- SEMA6C | c.1634G>C p.C545S | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100501028; called by muse, mutect2, varscan2
- SKIL | c.709C>G p.R237G | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.816); catalogued as rs367787976, COSV52060695; called by muse, mutect2, varscan2
- SLC30A4 | c.815G>C p.R272T | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs770957613; called by muse, mutect2, varscan2
- SNCAIP | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 125/353 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs546660788; called by muse, mutect2, varscan2
- SNTG1 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV52457073; called by muse, mutect2, varscan2
- SUPT5H | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 101/555 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV63239439; called by muse, mutect2, varscan2
- TBX3 | c.2026G>T p.A676S (on ENST00000257566 / NM_016569.4; = p.A656S on NM_005996.4) | Missense Mutation (SNP) | VAF 185/595 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1013102657, COSV57472702, COSV57473679; called by muse, mutect2, varscan2
- TENT5D | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV100383047, COSV57636713; called by muse, mutect2, varscan2
- TMEM273 | c.9G>C p.L3F | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs766618129; called by mutect2, varscan2
- TNN | c.136T>A p.Y46N | Missense Mutation (SNP) | VAF 80/436 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53422616; called by muse, mutect2, varscan2
- TTN | c.67210G>A p.E22404K (on ENST00000591111; = p.E14980K on NM_003319.4) | Missense Mutation (SNP) | VAF 83/396 reads (21%) | PolyPhen benign (0.443); catalogued as rs1406753487, COSV100599169; called by muse, mutect2, varscan2
- UBR4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1392862327; called by muse, mutect2, varscan2
- VIP | c.141T>G p.N47K | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1278490969; called by muse, mutect2, varscan2
- XPC | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 44/325 reads (14%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.054); catalogued as COSV53204715; called by muse, mutect2, varscan2
- ZBTB49 | c.1601C>A p.P534H | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100552526; called by muse, mutect2, varscan2
- ZNF786 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 90/427 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60277667; called by muse, mutect2, varscan2
- AAAS | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC015802.6 | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- AC098582.1 | c.1898A>T p.H633L | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ACE | c.2677G>A p.D893N | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ACVR1 | c.1367A>T p.N456I | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- ADAM29 | c.1804A>T p.T602S | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF1 | c.5542A>G p.K1848E | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ARNT | c.1150G>T p.V384F | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- BRWD1 | c.3857T>A p.L1286* | Nonsense Mutation (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- CABCOCO1 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CACNA1B | c.5591A>G p.Y1864C | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1F | c.5498G>C p.R1833T | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CCDC60 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 52/385 reads (14%) | called by muse, mutect2, varscan2
- CD160 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 80/403 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CEBPZ | c.2208G>C p.Q736H | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- CFAP44 | c.4849G>T p.V1617F | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CFAP92 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CFP | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 110/298 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- CKAP5 | c.2875G>C p.A959P | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CLEC20A | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); called by mutect2, varscan2
- COL26A1 | c.982C>G p.P328A (on ENST00000313669 / NM_001278563.3; = p.P326A on NM_133457.4) | Missense Mutation (SNP) | VAF 13/378 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2
- COL4A4 | c.4348A>T p.I1450F | Missense Mutation (SNP) | VAF 63/355 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CSF3 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 119/424 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CUEDC1 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CX3CR1 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 79/374 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYP2A13 | c.1001_1011del p.V334Efs*7 | Frame Shift Del (DEL) | VAF 47/299 reads (16%) | called by mutect2, pindel, varscan2
- DCHS2 | c.1585G>A p.V529I | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.047); called by muse, mutect2
- DDX39B | c.1224G>C p.E408D | Missense Mutation (SNP) | VAF 99/520 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX16 | c.2782G>T p.G928C | Missense Mutation (SNP) | VAF 74/418 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by mutect2, varscan2
- DNAH9 | c.12595G>A p.V4199M | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DZIP3 | c.2760A>C p.R920S | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ELN | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERI2 | c.650A>G p.D217G | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERICH1 | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 89/400 reads (22%) | called by muse, mutect2, varscan2
- ETAA1 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAF1 | c.1658T>A p.I553N | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FAM160A1 | c.847G>T p.V283F | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- FBN1 | c.4849T>G p.C1617G | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FZD9 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 75/393 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GAL3ST3 | c.1268T>A p.V423E | Missense Mutation (SNP) | VAF 55/293 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by mutect2, varscan2
- GCC2 | c.3001G>C p.E1001Q | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GEMIN6 | c.229A>G p.R77G | Missense Mutation (SNP) | VAF 82/493 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- GGT7 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJC1 | c.77C>G p.T26S | Missense Mutation (SNP) | VAF 59/458 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- GLI2 | c.1175T>A p.L392Q | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GPR176 | c.1454A>G p.E485G | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRM8 | c.428A>T p.K143M | Missense Mutation (SNP) | VAF 78/406 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- H2AC17 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.3); called by muse, varscan2
- HDAC4 | c.2494A>G p.S832G | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HECTD4 | c.9105G>T p.W3035C | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXD4 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFI16 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ILDR1 | c.1381A>T p.R461* (on ENST00000344209 / NM_001199799.2; = p.R417* on NM_175924.4) | Nonsense Mutation (SNP) | VAF 85/508 reads (17%) | called by muse, mutect2, varscan2
- IQUB | c.2016C>A p.D672E | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ITGA9 | c.1897G>C p.G633R | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- KCNH1 | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0319 | c.2747A>G p.K916R | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.411); called by muse, varscan2
- KMT2C | c.13702G>C p.A4568P | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KMT2C | c.5095G>C p.D1699H | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIPF | c.692T>A p.F231Y | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LOXHD1 | c.2125T>A p.Y709N | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- LRRC41 | c.187A>G p.S63G | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.205); called by mutect2, varscan2
- MEX3A | c.1154_1156delinsA p.A385Efs*3 | Frame Shift Del (DEL) | VAF 70/344 reads (20%) | called by pindel, varscan2*
- MMP27 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC17 | c.9649C>G p.P3217A | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NBPF10 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NECTIN1 | c.467T>G p.V156G | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEIL1 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- NEK5 | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- NKIRAS2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 67/420 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NOA1 | c.486G>C p.E162D | Missense Mutation (SNP) | VAF 79/405 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOMO2 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- OR2B6 | c.242T>G p.M81R | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- OR2D2 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- ORC5 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- OTOP1 | c.28T>A p.S10T | Missense Mutation (SNP) | VAF 94/304 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); called by muse, varscan2
- PAPPA2 | c.301G>T p.G101* | Nonsense Mutation (SNP) | VAF 127/375 reads (34%) | called by mutect2, varscan2
- PDS5A | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PLCD3 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 57/442 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PNISR | c.2282G>A p.S761N | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PNMA6E | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- PRXL2B | c.154-17_159del p.X52_splice (on ENST00000444521; = p.X22_splice on NM_152371.5 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 41/193 reads (21%) | called by mutect2, pindel, varscan2
- PTPRN2 | c.2152C>G p.P718A | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RHBDL2 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- RNF14 | c.1247G>C p.G416A | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN2B | c.151A>T p.T51S | Missense Mutation (SNP) | VAF 77/392 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- SEC14L3 | c.912G>T p.R304S | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.418); called by muse, mutect2
- SIRT7 | c.978_990del p.G327Pfs*52 | Frame Shift Del (DEL) | VAF 51/242 reads (21%) | called by pindel, varscan2
- SLC22A12 | c.1465C>G p.L489V | Missense Mutation (SNP) | VAF 76/459 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SLC25A15 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC26A9 | c.1833C>G p.N611K | Missense Mutation (SNP) | VAF 74/497 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC2A13 | c.1732del p.L578Sfs*25 | Frame Shift Del (DEL) | VAF 21/169 reads (12%) | called by pindel, varscan2
- SLC39A6 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- SNX15 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STXBP5 | c.2289C>G p.D763E (on ENST00000321680 / NM_001127715.2; = p.D727E on NM_139244.4) | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.6190G>T p.E2064* (on ENST00000367255 / NM_182961.4; = p.E2071* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 37/185 reads (20%) | called by muse, mutect2, varscan2
- TAOK1 | c.2444A>T p.Y815F | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TCAIM | c.1124G>A p.R375K | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TDRD15 | c.2923T>A p.Y975N | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TENT5D | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMM17A | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 34/339 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TPGS1 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 77/398 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF3IP3 | c.1569A>T p.Q523H | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); called by mutect2, varscan2
- TRIP12 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRMT61B | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRPM8 | c.2297C>G p.P766R | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by mutect2, varscan2
- UGT2A3 | c.75del p.V26Sfs*8 | Frame Shift Del (DEL) | VAF 65/356 reads (18%) | called by mutect2, pindel, varscan2
- VPS13A | c.1527G>C p.E509D | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- YRDC | c.388A>T p.R130* | Nonsense Mutation (SNP) | VAF 39/220 reads (18%) | called by muse, mutect2, varscan2
- ZNF217 | c.3062A>T p.H1021L | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- ZNF335 | c.1328G>T p.R443M | Missense Mutation (SNP) | VAF 78/526 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZNF391 | c.729C>A p.H243Q | Missense Mutation (SNP) | VAF 74/399 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF566 | c.855del p.C285* | Frame Shift Del (DEL) | VAF 36/248 reads (15%) | called by mutect2, pindel, varscan2
- ABCA6 | c.318G>A p.G106= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as rs767036591, COSV99446131; called by muse, mutect2, varscan2
- ABCC9 | c.3729G>A p.S1243= | Silent (SNP) | VAF 53/288 reads (18%) | catalogued as rs140182559; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACRV1 | c.624C>G p.T208= | Silent (SNP) | VAF 47/276 reads (17%) | called by muse, mutect2, varscan2
- AOC1 | c.819T>C p.H273= | Silent (SNP) | VAF 87/442 reads (20%) | called by muse, mutect2, varscan2
- AOX1 | c.1677A>G p.K559= | Silent (SNP) | VAF 44/240 reads (18%) | called by muse, mutect2, varscan2
- APBB1IP | c.1677G>A p.P559= | Silent (SNP) | VAF 56/309 reads (18%) | catalogued as rs1481662367; called by mutect2, varscan2
- ARMH3 | c.1788C>A p.I596= | Silent (SNP) | VAF 49/266 reads (18%) | catalogued as COSV64235522; called by muse, mutect2, varscan2
- BNC2 | c.2346T>A p.T782= | Silent (SNP) | VAF 80/322 reads (25%) | called by muse, mutect2, varscan2
- BSN | c.10014C>T p.P3338= | Silent (SNP) | VAF 63/318 reads (20%) | catalogued as rs866608898, COSV99609915; called by muse, mutect2, varscan2
- BSPRY | c.1071G>A p.V357= | Silent (SNP) | VAF 71/492 reads (14%) | called by muse, mutect2, varscan2
- CCDC71L | c.636G>A p.R212= | Silent (SNP) | VAF 86/434 reads (20%) | catalogued as rs761200837; called by muse, mutect2, varscan2
- CCL23 | c.171C>A p.T57= | Silent (SNP) | VAF 54/307 reads (18%) | called by muse, mutect2, varscan2
- CELSR2 | c.4569G>A p.L1523= | Silent (SNP) | VAF 62/308 reads (20%) | catalogued as COSV54774412; called by muse, mutect2, varscan2
- CLIP1 | c.753G>A p.G251= | Silent (SNP) | VAF 57/356 reads (16%) | called by muse, mutect2, varscan2
- CMPK2 | c.1302C>T p.V434= | Silent (SNP) | VAF 49/288 reads (17%) | called by muse, mutect2, varscan2
- COL12A1 | c.4905T>A p.S1635= | Silent (SNP) | VAF 57/417 reads (14%) | catalogued as rs1262898971; called by muse, mutect2, varscan2
- COL14A1 | c.4989C>G p.G1663= | Silent (SNP) | VAF 76/422 reads (18%) | called by muse, mutect2, varscan2
- COL4A3 | c.1800T>C p.D600= | Silent (SNP) | VAF 51/305 reads (17%) | called by muse, mutect2, varscan2
- COL7A1 | c.2208G>T p.T736= | Silent (SNP) | VAF 66/273 reads (24%) | called by muse, mutect2, varscan2
- CSMD1 | c.5238C>T p.P1746= (on ENST00000520002; = p.P1745= on NM_033225.6) | Silent (SNP) | VAF 11/275 reads (4%) | catalogued as rs1474815603; called by muse, mutect2
- DAW1 | c.81T>G p.T27= | Silent (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- DENND1A | c.2397G>A p.P799= | Silent (SNP) | VAF 77/426 reads (18%) | catalogued as rs761760279, COSV101011994; called by muse, mutect2, varscan2
- DEPDC1B | c.342A>G p.P114= | Silent (SNP) | VAF 38/193 reads (20%) | catalogued as rs1336436001, COSV54009979; called by muse, mutect2, varscan2
- DIP2B | c.2022T>G p.A674= | Silent (SNP) | VAF 39/283 reads (14%) | called by muse, mutect2, varscan2
- DSC1 | c.2604G>A p.R868= | Silent (SNP) | VAF 48/314 reads (15%) | called by muse, mutect2, varscan2
- FHOD3 | c.1098G>A p.S366= | Silent (SNP) | VAF 80/391 reads (20%) | catalogued as rs771725122, COSV57174518, COSV57180082; called by muse, mutect2, varscan2
- FZD10 | c.198C>A p.I66= | Silent (SNP) | VAF 80/522 reads (15%) | called by muse, mutect2, varscan2
- GEN1 | c.138C>G p.G46= | Silent (SNP) | VAF 47/239 reads (20%) | called by muse, mutect2, varscan2
- GJA8 | c.609C>A p.T203= | Silent (SNP) | VAF 87/455 reads (19%) | catalogued as COSV53789693; called by muse, mutect2, varscan2
- GJB5 | c.504A>G p.P168= | Silent (SNP) | VAF 63/357 reads (18%) | called by muse, mutect2, varscan2
- GLB1L2 | c.49C>T p.L17= | Silent (SNP) | VAF 63/341 reads (18%) | called by muse, mutect2, varscan2
- GOT2 | c.48C>T p.A16= | Silent (SNP) | VAF 86/375 reads (23%) | called by muse, mutect2, varscan2
- GSK3B | c.450A>G p.K150= | Silent (SNP) | VAF 66/292 reads (23%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.735C>T p.S245= | Silent (SNP) | VAF 70/298 reads (23%) | called by muse, mutect2, varscan2
- KIRREL1 | c.423C>T p.L141= | Silent (SNP) | VAF 97/530 reads (18%) | called by muse, varscan2
- LARS1 | c.1242A>G p.A414= (on ENST00000394434 / NM_020117.11; = p.A387= on NM_016460.3) | Silent (SNP) | VAF 49/158 reads (31%) | called by muse, mutect2, varscan2
- MMP14 | c.1113C>A p.A371= | Silent (SNP) | VAF 75/355 reads (21%) | called by muse, mutect2, varscan2
- MTMR11 | c.1587A>G p.Q529= (on ENST00000439741 / NM_001145862.2; = p.Q457= on NM_181873.3) | Silent (SNP) | VAF 67/355 reads (19%) | catalogued as rs1365976201; called by muse, mutect2, varscan2
- MUC13 | c.1239C>A p.L413= | Silent (SNP) | VAF 61/362 reads (17%) | called by muse, mutect2, varscan2
- NFKBIL1 | c.606A>C p.S202= | Silent (SNP) | VAF 72/497 reads (14%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5454G>A p.L1818= | Silent (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- OR1G1 | c.801G>A p.S267= | Silent (SNP) | VAF 144/354 reads (41%) | catalogued as rs750476332, COSV61030046; called by muse, varscan2
- OR5D16 | c.60A>T p.S20= | Silent (SNP) | VAF 57/316 reads (18%) | called by muse, mutect2, varscan2
- OR5I1 | c.351G>T p.L117= | Silent (SNP) | VAF 64/364 reads (18%) | called by muse, mutect2, varscan2
- P2RX3 | c.729C>T p.I243= | Silent (SNP) | VAF 73/364 reads (20%) | catalogued as COSV54443140, COSV54443283; called by muse, varscan2
- PCDHA8 | c.1842T>A p.A614= | Silent (SNP) | VAF 168/435 reads (39%) | catalogued as rs782268350; called by muse, mutect2, varscan2
- PEX6 | c.2199G>C p.L733= | Silent (SNP) | VAF 74/429 reads (17%) | called by muse, mutect2, varscan2
- PKD1 | c.4584C>T p.A1528= | Silent (SNP) | VAF 77/423 reads (18%) | catalogued as rs149007676; called by muse, mutect2, varscan2
- PXMP2 | c.228C>T p.A76= | Silent (SNP) | VAF 38/269 reads (14%) | catalogued as rs367671261; called by muse, mutect2, varscan2
- RPS16 | c.252C>T p.I84= | Silent (SNP) | VAF 56/266 reads (21%) | catalogued as COSV99261782; called by muse, mutect2, varscan2
- SGK2 | c.531C>T p.N177= | Silent (SNP) | VAF 72/287 reads (25%) | catalogued as rs143273559; called by muse, mutect2, varscan2
- SLC12A5 | c.2493C>G p.T831= (on ENST00000454036 / NM_001134771.2; = p.T808= on NM_020708.5) | Silent (SNP) | VAF 125/508 reads (25%) | called by muse, mutect2, varscan2
- SNCAIP | c.2418T>C p.R806= | Silent (SNP) | VAF 129/321 reads (40%) | catalogued as rs763248848; called by muse, mutect2, varscan2
- SPICE1 | c.399A>C p.V133= | Silent (SNP) | VAF 33/186 reads (18%) | called by muse, mutect2, varscan2
- ST7 | c.1527G>A p.K509= (on ENST00000265437 / NM_021908.3; = p.K486= on NM_018412.4) | Silent (SNP) | VAF 35/185 reads (19%) | called by muse, mutect2, varscan2
- SYCP2 | c.3180G>T p.T1060= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as rs751528651, COSV100698198, COSV62771166; called by muse, mutect2, varscan2
- TAS1R2 | c.1794G>A p.S598= | Silent (SNP) | VAF 105/397 reads (26%) | called by muse, mutect2, varscan2
- TIMM8A | c.27G>T p.A9= | Silent (SNP) | VAF 41/157 reads (26%) | called by muse, mutect2, varscan2
- TMDD1 | c.705G>A p.A235= | Silent (SNP) | VAF 51/365 reads (14%) | called by muse, mutect2, varscan2
- TMEM132C | c.603G>T p.L201= | Silent (SNP) | VAF 77/553 reads (14%) | called by muse, mutect2, varscan2
- VPS13A | c.3888A>G p.E1296= | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- ZNF334 | c.45G>T p.L15= | Silent (SNP) | VAF 46/366 reads (13%) | called by muse, mutect2, varscan2
- ZP3 | c.957T>C p.C319= (on ENST00000394857 / NM_001110354.2; = p.C268= on NM_007155.6) | Silent (SNP) | VAF 65/372 reads (17%) | called by muse, mutect2, varscan2
- DNMBP | c.2261-21443C>T | Intron (SNP) | VAF 75/423 reads (18%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899519 A>G | 3'Flank (SNP) | VAF 59/308 reads (19%) | called by muse, mutect2, varscan2
- LMO2 | c.-194C>T | 5'UTR (SNP) | VAF 47/236 reads (20%) | catalogued as rs1391935903; called by muse, varscan2
- NACA | c.70+3800C>T | Intron (SNP) | VAF 47/302 reads (16%) | catalogued as rs768822329; called by muse, mutect2, varscan2
- NBR1 | c.*644G>C | 3'UTR (SNP) | VAF 39/355 reads (11%) | called by muse, mutect2
- NEB | c.8890-3120G>A | Intron (SNP) | VAF 41/246 reads (17%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31354G>A | Intron (SNP) | VAF 53/263 reads (20%) | catalogued as rs1183763274; called by muse, mutect2, varscan2
- SMARCE1 | c.1027+44T>C | Intron (SNP) | VAF 58/403 reads (14%) | called by muse, mutect2, varscan2
- UCK2 | c.100-4838C>G | Intron (SNP) | VAF 42/204 reads (21%) | called by muse, mutect2, varscan2
- WDR49 | c.-65-17102A>T | Intron (SNP) | VAF 135/386 reads (35%) | called by muse, mutect2, varscan2
